Somatic mutation profile of tumor specimen TCGA-MQ-A4LJ-01A (aliquot TCGA-MQ-A4LJ-01A-11D-A34C-32) from TCGA case TCGA-MQ-A4LJ, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 53.2 years (19,437 days).
Specimen TCGA-MQ-A4LJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c685296-f476-4da9-a860-45db1bb99281.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MQ-A4LJ-10B (Blood Derived Normal), aliquot TCGA-MQ-A4LJ-10B-01D-A34C-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5415a7bd-953b-41ca-8354-190df9864eb7

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 10, Silent 5, Nonsense Mutation 2, Frame Shift Del 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSM3 | c.605G>C p.R202T | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs752542843, COSV55501494; called by muse, mutect2, varscan2
- C9orf85 | c.298G>T p.G100* | Nonsense Mutation (SNP) | VAF 13/33 reads (39%) | catalogued as COSV58253198; called by muse, mutect2, varscan2
- GRM8 | c.69G>T p.W23C | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as rs1305115149; called by muse, mutect2, varscan2
- KSR1 | c.488C>T p.A163V (on ENST00000644974 / NM_001367810.1; = p.A26V on NM_014238.2) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as rs746238178; called by muse, mutect2, varscan2
- NLRP4 | c.2420A>G p.K807R | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.305); catalogued as rs770786832; called by muse, mutect2, varscan2
- RPL14 | c.446_447insCTGCTGCTG p.T149_A150insCCC | In Frame Ins (INS) | VAF 3/28 reads (11%) | catalogued as COSV59083389; called by pindel, varscan2*
- ZNF23 | c.596C>T p.S199L | Missense Mutation (SNP) | VAF 40/69 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs371943450; called by muse, mutect2, varscan2
- ATAD1 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CASP8AP2 | c.664_683del p.C222Tfs*10 | Frame Shift Del (DEL) | VAF 50/226 reads (22%) | called by mutect2, pindel, varscan2
- DNAJC13 | c.2547A>T p.R849S | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NCKAP5L | c.2434_2436delinsT p.H812* | Frame Shift Del (DEL) | VAF 34/91 reads (37%) | called by pindel, varscan2*
- PHRF1 | c.1529T>A p.L510Q (on ENST00000264555 / NM_001286581.2; = p.L509Q on NM_020901.4) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRMT11 | c.761G>A p.G254E | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- WDFY3 | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 21/75 reads (28%) | called by muse, mutect2, varscan2
- ZKSCAN7 | c.207G>C p.Q69H | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CD163 | c.1428G>A p.R476= | Silent (SNP) | VAF 30/86 reads (35%) | catalogued as COSV100775743; called by muse, mutect2, varscan2
- KANSL3 | c.1482C>G p.P494= | Silent (SNP) | VAF 30/86 reads (35%) | called by muse, mutect2, varscan2
- LCT | c.5721G>A p.K1907= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs763211653; called by muse, mutect2
- PPP1R13L | c.1806G>T p.P602= | Silent (SNP) | VAF 11/30 reads (37%) | called by muse, mutect2, varscan2
- TOR2A | c.912C>A p.L304= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as rs1436320765, COSV60162072; called by muse, mutect2, varscan2
